Somatic mutation profile of tumor specimen TARGET-10-PATKVD-09A (aliquot TARGET-10-PATKVD-09A-01D) from TARGET case TARGET-10-PATKVD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (904 days).
Specimen TARGET-10-PATKVD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef3eb6e0-af94-4091-8616-5d613cc022cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATKVD-10A (Blood Derived Normal), aliquot TARGET-10-PATKVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29e42639-0302-4813-b5b6-89ad40235eb6

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, 3'UTR 3, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 160/179 reads (89%) | catalogued as rs786204928, CM992426, COSV64292229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CBX7 | c.192_193insTTTTAACCGTGC p.D64_R65insF* | Nonsense Mutation (INS) | VAF 41/128 reads (32%) | catalogued as COSV53358548; called by mutect2, pindel, varscan2
- ESPNL | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs769215356, COSV58035889; called by muse, mutect2, varscan2
- FBXO46 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as COSV58348982; called by muse, mutect2
- MYB | c.436T>C p.S146P | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV57199208; called by muse, mutect2, varscan2
- NOTCH1 | c.7375C>T p.Q2459* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as rs1292613938, COSV53025731; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2
- OSBPL6 | c.242C>A p.T81N | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.115); catalogued as COSV51921534; called by muse, mutect2
- TBC1D16 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs755493757, COSV60478890; called by muse, mutect2, varscan2
- ATG4D | c.1109_1110insAGATAGTCAGA p.D370Efs*47 | Frame Shift Ins (INS) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- TNIK | c.2911G>T p.A971S | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- RIMS1 | c.4944G>C p.L1648= | Silent (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- SYNE1 | c.3903G>A p.Q1301= (on ENST00000367255 / NM_182961.4; = p.Q1308= on NM_033071.3) | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV55055572; called by muse, mutect2
- ZFHX2 | c.1950G>A p.P650= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs1024653392; called by muse, mutect2, varscan2
- ZNF469 | c.6978G>A p.T2326= (on ENST00000437464; = p.T2354= on NM_001367624.2) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs866760637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDIL3 | c.1137+12224T>C | Intron (SNP) | VAF 10/19 reads (53%) | catalogued as rs1433194912; called by muse, mutect2
- GNPAT | c.*27C>T | 3'UTR (SNP) | VAF 47/98 reads (48%) | catalogued as rs774351267, COSV100791583; called by muse, mutect2, varscan2
- KCTD8 | c.*51T>G | 3'UTR (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- TDGF1 | c.*41A>G | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
